Somatic mutation profile of tumor specimen C3N-00334-02 (aliquot CPT0018570006) from CPTAC case C3N-00334, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.4 years (24,976 days).
Specimen C3N-00334-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79e9f980-468c-40bb-b25a-3856d3eb5144.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00334-31 (Blood Derived Normal), aliquot CPT0018720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ee601b-0b9b-43a3-93d0-9dbc745e8b87

The open-access MAF lists 502 somatic variants for this specimen: 343 protein-altering or splice-affecting, 89 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 89, Frame Shift Del 87, Intron 33, 3'UTR 14, Frame Shift Ins 13, RNA 10, Nonsense Mutation 9, 5'UTR 6, Splice Site 5, 5'Flank 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 153/520 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 74/270 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 78/269 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1262del p.P421Hfs*16 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | catalogued as rs751253143; called by mutect2, pindel, varscan2
- AC092143.1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 139/598 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs372044268; called by muse, mutect2, varscan2
- AC231657.3 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1557083292; called by muse, mutect2, varscan2
- ADGRD2 | c.2243G>A p.C748Y | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100601383; called by muse, mutect2, varscan2
- AGPAT5 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99576350; called by muse, mutect2, varscan2
- ALG1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 86/415 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs748038529; called by muse, mutect2, varscan2
- AMER3 | c.1669dup p.A557Gfs*54 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | catalogued as rs756385870; called by mutect2, varscan2
- ANAPC2 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137952224; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 72/153 reads (47%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID2 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57600739; called by mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 48/188 reads (26%) | catalogued as rs772181094; called by mutect2, varscan2
- AXIN2 | c.1304C>A p.P435Q | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100196856; called by muse, mutect2, varscan2
- AZIN2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs746194223, COSV53860936; called by muse, mutect2, varscan2
- B4GALT6 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs143211727; called by muse, mutect2, varscan2
- BARHL1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV99707753; called by muse, mutect2, varscan2
- C3AR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756745490, COSV50817573; called by muse, mutect2, varscan2
- CACNB2 | c.1829G>A p.R610Q (on ENST00000324631 / NM_201596.3; = p.R555Q on NM_000724.4) | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.079); catalogued as rs781454884, COSV56637779; called by muse, mutect2, varscan2
- CADM3 | c.519C>T p.H173= (on ENST00000368125 / NM_001127173.3; = p.H207= on NM_021189.5) | Splice Region (SNP) | VAF 49/173 reads (28%) | catalogued as rs200132536; called by muse, mutect2, varscan2
- CARMIL1 | c.3889C>G p.L1297V | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.232); catalogued as rs772540078; called by muse, mutect2, varscan2
- CASD1 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV51970688; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs397851855; called by mutect2, varscan2
- CDH19 | c.1745G>A p.C582Y | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748560534; called by muse, mutect2, varscan2
- CDH3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs752908359; called by muse, mutect2, varscan2
- CEP135 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs199977626; called by muse, mutect2, varscan2
- CEP89 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV54287600; called by muse, mutect2, varscan2
- CER1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs140434620; called by muse, mutect2, varscan2
- CHPF2 | c.1941dup p.S648Lfs*6 | Frame Shift Ins (INS) | VAF 11/70 reads (16%) | catalogued as rs746469175; called by mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs752250702; called by mutect2, varscan2
- CLINT1 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1561632422; called by muse, mutect2
- CNPY4 | c.249_250del p.X83_splice | Splice Site (DEL) | VAF 40/189 reads (21%) | catalogued as rs751666560; called by pindel, varscan2
- CNTNAP4 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs35988001; called by muse, mutect2, varscan2
- COBL | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751920839; called by muse, mutect2, varscan2
- COL5A2 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772811492, COSV66407304; ClinVar: uncertain significance; called by muse, varscan2
- COLGALT1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772191035; called by muse, mutect2, varscan2
- CPT1B | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.974); catalogued as rs1030356387; called by muse, mutect2, varscan2
- CRCT1 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 35/134 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV57500352; called by muse, mutect2, varscan2
- CRHBP | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV57189466; called by muse, mutect2, varscan2
- CSTF2T | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 87/455 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs866466836, COSV100484273; called by muse, mutect2, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs201169323; called by mutect2, pindel, varscan2
- DCC | c.3691del p.R1231Gfs*5 | Frame Shift Del (DEL) | VAF 52/238 reads (22%) | catalogued as rs1568151221; called by mutect2, varscan2
- DEF8 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs778849246; called by muse, mutect2, varscan2
- DHX16 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs768020321, COSV64563017; called by muse, mutect2
- DICER1 | c.3767C>A p.P1256H | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.416); catalogued as COSV58615909; called by muse, mutect2, varscan2
- DMXL2 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761923802, COSV51847389; called by muse, mutect2, varscan2
- DNAH17 | c.10358A>G p.K3453R | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs750821611; called by muse, mutect2, varscan2
- DNAH3 | c.9907A>G p.T3303A | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54556304; called by muse, mutect2, varscan2
- DPH5 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587441; called by muse, mutect2, varscan2
- DYSF | c.3937del p.Q1313Rfs*32 | Frame Shift Del (DEL) | VAF 78/375 reads (21%) | catalogued as COSV50542787; called by pindel, varscan2
- ECSIT | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs758391824; called by muse, mutect2, varscan2
- EHD4 | c.1579del p.H527Tfs*37 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs758354312; called by mutect2, pindel
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EPHX3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1226054291, COSV55655559; called by muse, mutect2, varscan2
- EZR | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469513132; called by muse, mutect2, varscan2
- FAM149B1 | c.1529_1532del p.N510Ifs*89 | Frame Shift Del (DEL) | VAF 43/246 reads (17%) | catalogued as rs1280925560; called by mutect2, pindel, varscan2
- FAM166B | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1038586653; called by muse, mutect2
- FANCD2 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs746265846; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FOXI1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60388720; called by muse, mutect2, varscan2
- GGCX | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763574311; called by muse, mutect2, varscan2
- GP9 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1275173565; called by muse, mutect2
- GPR39 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.19); catalogued as rs1217617986, COSV61415807; called by muse, mutect2, varscan2
- GRIN2B | c.3295C>A p.R1099S | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.804); catalogued as CD129429, COSV101663170; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs754199513; called by mutect2, varscan2
- H2AC6 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 54/278 reads (19%) | catalogued as rs750507873; called by pindel, varscan2
- HECW1 | c.4351G>A p.G1451S | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1366110534, COSV101224302, COSV67827012; called by muse, mutect2, varscan2
- HHAT | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs145435771, COSV54801295; called by muse, mutect2
- HNRNPA0 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs1024716394; called by muse, varscan2
- HSF5 | c.173del p.G58Afs*131 | Frame Shift Del (DEL) | VAF 46/189 reads (24%) | catalogued as rs1555645044; called by mutect2, pindel, varscan2
- HYDIN | c.1973G>T p.R658M | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99864203; called by muse, mutect2, varscan2
- INPP4A | c.2917G>A p.G973R (on ENST00000074304 / NM_001134224.1; = p.G934R on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs76257041, COSV50802183; called by muse, mutect2, varscan2
- INPP5F | c.788dup p.Q264Sfs*8 | Frame Shift Ins (INS) | VAF 22/104 reads (21%) | catalogued as rs750419826; called by mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | catalogued as rs1561359523; called by mutect2, varscan2
- ITGA11 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764516782; called by muse, mutect2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel
- KCP | c.2739del p.D914Tfs*111 (on ENST00000620378; = p.D974Tfs*111 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 33/158 reads (21%) | catalogued as rs778175457; called by mutect2, pindel, varscan2
- KIAA1109 | c.10292C>T p.T3431I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV52699610; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF7 | c.2800del p.E934Rfs*16 | Frame Shift Del (DEL) | VAF 57/284 reads (20%) | catalogued as COSV99177598; called by mutect2, pindel, varscan2
- KMT2C | c.14483G>A p.R4828H | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796342, COSV51436921; ClinVar: uncertain significance; called by muse, mutect2
- LCE1A | c.54del p.K19Sfs*51 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | catalogued as rs770406142, COSV58727600, COSV58727695; called by pindel, varscan2
- LMOD3 | c.444A>T p.E148D | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs185938792, COSV70455916; called by muse, mutect2, varscan2
- LPCAT1 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV52036747, COSV99358898; called by muse, mutect2, varscan2
- LRFN2 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57823665; called by muse, mutect2
- MAP3K1 | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 94/386 reads (24%) | catalogued as COSV68124040; called by muse, mutect2, varscan2
- MARK4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs779413121; called by muse, varscan2
- MBD1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 96/442 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs146267961; called by muse, mutect2, varscan2
- MCM3AP | c.5012C>T p.P1671L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs752671874; called by muse, mutect2, varscan2
- MCM3AP | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs778878854; called by muse, mutect2
- MED12L | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs866960428, COSV56388799; called by muse, mutect2, varscan2
- MROH2B | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV68184865; called by muse, mutect2, varscan2
- MRTFA | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs769458301; called by muse, mutect2, varscan2
- MTA1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs782787159; called by muse, mutect2, varscan2
- MYH2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 99/529 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1433670000, COSV55440994; called by muse, mutect2, varscan2
- NALCN | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.605); catalogued as COSV99078465; called by muse, mutect2, varscan2
- NAV2 | c.1328C>T p.P443L (on ENST00000396087 / NM_001244963.2; = p.P420L on NM_145117.5) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs747003174; called by muse, mutect2, varscan2
- NEB | c.9938A>C p.Q3313P | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV51449384; called by muse, mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 85/303 reads (28%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NOC2L | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs372047419; called by muse, mutect2, varscan2
- NOP2 | c.1226C>T p.T409M (on ENST00000322166 / NM_001258308.2; = p.T405M on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773616064; called by muse, mutect2, varscan2
- NRCAM | c.382G>A p.E128K (on ENST00000379028 / NM_001371124.1; = p.E122K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.1); catalogued as rs1195662054; called by muse, mutect2, varscan2
- NVL | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs769948002, COSV55876265; called by muse, mutect2, varscan2
- OLFM3 | c.710G>A p.R237Q (on ENST00000338858 / NM_001288821.1; = p.R217Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58797459; called by muse, mutect2, varscan2
- OR10H1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs1349572473; called by muse, mutect2, varscan2
- OR2F1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs765028132; called by muse, mutect2, varscan2
- OR2M3 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV71759120; called by muse, mutect2, varscan2
- PAPPA2 | c.1229del p.G410Efs*47 | Frame Shift Del (DEL) | VAF 51/229 reads (22%) | catalogued as COSV62772783; called by mutect2, pindel, varscan2
- PCDHGA6 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs868822562; called by muse, mutect2, varscan2
- PCNX2 | c.6314C>T p.A2105V | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.194); catalogued as COSV99269071; called by muse, mutect2, varscan2
- PCSK5 | c.4289C>T p.S1430L | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs761738274, COSV70450964; called by muse, mutect2, varscan2
- PDK4 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs149188261; called by muse, mutect2, varscan2
- PEDS1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59014001; called by muse, mutect2, varscan2
- PHTF1 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as rs541473691; called by muse, mutect2, varscan2
- PI4KA | c.4928G>A p.R1643Q | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs373067047; called by muse, mutect2, varscan2
- PI4KA | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1456758190, COSV55425796; called by muse, mutect2, varscan2
- PLA2G4C | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs768011771, COSV62788615; called by muse, mutect2, varscan2
- PLEKHG4 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as rs369151536; called by muse, mutect2, varscan2
- PLXND1 | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs766394256; called by muse, mutect2, varscan2
- POGZ | c.3260G>A p.R1087Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.157); catalogued as rs376406028, COSV51852657; called by muse, mutect2, varscan2
- POLE3 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748327091, COSV55911742; called by muse, mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 40/207 reads (19%) | catalogued as rs753626854; called by mutect2, varscan2
- PPFIA3 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs1371239823; called by muse, mutect2, varscan2
- PPFIA4 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs767241944; called by muse, mutect2, varscan2
- PPP2CB | c.849del p.K283Nfs*45 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as COSV55329081; called by mutect2, pindel, varscan2
- PRAM1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55316121; called by muse, mutect2, varscan2
- PRELP | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs769853011; called by muse, mutect2, varscan2
- PRF1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs754602851, COSV64614624; called by muse, mutect2, varscan2
- PRSS8 | c.124del p.Q42Kfs*64 | Frame Shift Del (DEL) | VAF 35/190 reads (18%) | catalogued as COSV99571515; called by mutect2, pindel, varscan2
- PTEN | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 200/373 reads (54%) | catalogued as COSV64296565, COSV64297504; called by muse, mutect2, varscan2
- PTPRS | c.1821del p.V608Wfs*30 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | catalogued as COSV53615889; called by mutect2, pindel
- PWWP3A | c.1022G>A p.R341H (on ENST00000627377; = p.R340H on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as rs565586522; called by muse, mutect2, varscan2
- RASA1 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV57193881; called by muse, mutect2, varscan2
- RBPJL | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59212519; called by muse, mutect2, varscan2
- RGS6 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.155); catalogued as COSV59581346; called by muse, mutect2, varscan2
- RNF207 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1438777755; called by muse, mutect2, varscan2
- RYR1 | c.10219G>A p.A3407T | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs143533100, CM147854, CM157085; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SEMA6D | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369660405, COSV100316624; called by muse, mutect2, varscan2
- SGK2 | c.116del p.P39Qfs*23 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs750160588; called by mutect2, pindel, varscan2
- SHOX2 | c.976G>A p.A326T (on ENST00000441443 / NM_006884.3; = p.A350T on NM_003030.4) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1476417389, COSV67464307; called by muse, mutect2
- SIRPG | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1475658105; called by muse, mutect2, varscan2
- SLC22A4 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99569536; called by muse, mutect2, varscan2
- SLC25A31 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372369477; called by muse, mutect2, varscan2
- SLC52A2 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1173664250, COSV57352143; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as rs1257129093; called by pindel, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs758895137; called by mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPOCD1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV57096826; called by muse, mutect2, varscan2
- SPRY4 | c.809G>A p.R270H (on ENST00000434127 / NM_001127496.3; = p.R293H on NM_030964.4) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748690914; called by muse, mutect2, varscan2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2, varscan2
- SV2A | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367547269, COSV100974983; called by muse, mutect2, varscan2
- TANC2 | c.1534A>G p.M512V | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs199687343; called by muse, mutect2, varscan2
- TBR1 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV101271573; called by muse, mutect2, varscan2
- TNS2 | c.764C>T p.A255V (on ENST00000314250 / NM_170754.4; = p.A265V on NM_015319.2) | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs776215521; called by muse, mutect2, varscan2
- TOB2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs563028453; called by muse, mutect2, varscan2
- TP53BP1 | c.2130del p.E711Nfs*12 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs1375740992, COSV55498775; called by mutect2, pindel, varscan2
- TRAPPC9 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs746266971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIB2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as rs546825227, COSV50224529; called by muse, varscan2
- TRIM51GP | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs571910105; called by muse, mutect2, varscan2
- TRPC6 | c.1556del p.K519Rfs*16 | Frame Shift Del (DEL) | VAF 87/355 reads (25%) | catalogued as COSV60251593; called by mutect2, pindel, varscan2
- TSPOAP1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52104641; called by muse, mutect2, varscan2
- TUBB4A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 103/422 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs587777429, CM146108, COSV51155246; called by muse, mutect2, varscan2
- TYRO3 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1376334073; called by muse, mutect2, varscan2
- UBASH3A | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs943156421; called by muse, mutect2
- UBXN10 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs752763316; called by muse, mutect2, varscan2
- UGT1A1 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as CM062019; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | catalogued as rs572063854; called by mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS13B | c.1654T>C p.S552P | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1249571800; called by muse, mutect2, varscan2
- VWF | c.7130dup p.H2378Afs*13 | Frame Shift Ins (INS) | VAF 45/274 reads (16%) | catalogued as rs267607359; ClinVar: not provided; called by mutect2, pindel, varscan2
- WDR18 | c.701del p.G234Afs*39 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV52121253; called by mutect2, pindel, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 31/170 reads (18%) | catalogued as rs750038548; called by mutect2, varscan2
- WNT4 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as rs772656483, COSV51604613; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs1403895317; called by mutect2, pindel, varscan2
- ZCCHC7 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs150280320; called by muse, mutect2, varscan2
- ZFP90 | c.1780del p.T594Pfs*57 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as rs747260313; called by mutect2, varscan2
- ZNF275 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782513606; called by muse, mutect2, varscan2
- ZNF653 | c.1666del p.L556Cfs*20 | Frame Shift Del (DEL) | VAF 37/246 reads (15%) | catalogued as rs1321729149, COSV53402096; called by mutect2, pindel, varscan2
- ZSCAN5C | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV104426627; called by muse, mutect2, varscan2
- ZXDC | c.2369A>G p.Q790R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV67628471; called by muse, mutect2, varscan2
- ACTL7B | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ACTN3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY1 | c.3172A>T p.T1058S | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AKAP4 | c.61del p.R21Gfs*6 | Frame Shift Del (DEL) | VAF 39/213 reads (18%) | called by mutect2, pindel, varscan2
- AL512785.2 | c.-12+8C>T | Splice Region (SNP) | VAF 56/286 reads (20%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK1 | c.2220dup p.E741Rfs*5 | Frame Shift Ins (INS) | VAF 33/189 reads (17%) | called by mutect2, pindel, varscan2
- AMMECR1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ARID1B | c.2030del p.T677Rfs*7 | Frame Shift Del (DEL) | VAF 16/167 reads (10%) | called by mutect2, pindel
- ARID2 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSD | c.775A>T p.M259L | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ASGR2 | c.425-1G>A p.X142_splice | Splice Site (SNP) | VAF 57/223 reads (26%) | called by muse, mutect2, varscan2
- ATXN1 | c.1314_1315del p.H438Qfs*60 | Frame Shift Del (DEL) | VAF 50/255 reads (20%) | called by pindel, varscan2
- B3GALT5 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.2384T>C p.I795T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- BPIFB4 | c.1344+1G>A p.X448_splice | Splice Site (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- BPTF | c.7079-1G>T p.X2360_splice | Splice Site (SNP) | VAF 28/64 reads (44%) | called by muse, varscan2
- BSN | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- BSX | c.172del p.L58Sfs*97 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- C12orf60 | c.180del p.F60Lfs*14 | Frame Shift Del (DEL) | VAF 45/150 reads (30%) | called by mutect2, pindel, varscan2
- C4orf19 | c.856dup p.E286Gfs*27 | Frame Shift Ins (INS) | VAF 26/124 reads (21%) | called by mutect2, pindel, varscan2
- C5orf52 | c.383del p.K128Sfs*3 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | called by mutect2, varscan2
- C8orf34 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- CAMKK1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- CAMTA1 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CASR | c.676T>A p.F226I | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CBLB | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CCDC175 | c.962del p.F321Sfs*8 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- CD2BP2 | c.974del p.P325Lfs*58 | Frame Shift Del (DEL) | VAF 53/201 reads (26%) | called by mutect2, pindel, varscan2
- CDH4 | c.2583del p.Y862Mfs*22 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- CEMIP2 | c.234A>T p.R78S | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CFAP43 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CHD9 | c.1932del p.K644Nfs*6 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | called by mutect2, pindel, varscan2
- CHST10 | c.923T>A p.I308N | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CLMN | c.2141del p.P714Hfs*31 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | called by mutect2, pindel, varscan2
- CNNM3 | c.961dup p.L321Pfs*104 | Frame Shift Ins (INS) | VAF 33/118 reads (28%) | called by mutect2, pindel
- CNTN4 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COX7B2 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CPEB2 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.803); called by muse, varscan2
- CPEB2 | c.2590G>T p.D864Y | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CRIPT | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX2 | c.4286del p.P1429Lfs*23 | Frame Shift Del (DEL) | VAF 51/204 reads (25%) | called by mutect2, pindel, varscan2
- DAB2 | c.86del p.K29Rfs*12 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | called by mutect2, pindel, varscan2
- DCAF11 | c.1528_1529del p.W510Afs*6 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by pindel, varscan2
- DCBLD1 | c.1787del p.P596Rfs*47 | Frame Shift Del (DEL) | VAF 56/282 reads (20%) | called by mutect2, pindel, varscan2
- DHX36 | c.578del p.N193Mfs*25 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, varscan2
- DNAH2 | c.6542T>C p.V2181A | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DSC1 | c.1625dup p.N542Kfs*28 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ELAPOR1 | c.1151C>A p.P384Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPP3 | c.26C>G p.T9R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- EPB41L3 | c.2593C>T p.H865Y | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- EVPLL | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- EXPH5 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM169A | c.1373T>C p.L458S | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2
- FAR1 | c.1446del p.F482Lfs*32 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- FASN | c.4057del p.L1353Sfs*20 | Frame Shift Del (DEL) | VAF 30/304 reads (10%) | called by mutect2, pindel
- FHOD3 | c.2564del p.P855Lfs*21 (on ENST00000359247 / NM_001281739.3; = p.P872Lfs*21 on NM_025135.5) | Frame Shift Del (DEL) | VAF 70/254 reads (28%) | called by mutect2, pindel, varscan2
- FRK | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GABBR2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABBR2 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALC | c.1884del p.K628Nfs*7 | Frame Shift Del (DEL) | VAF 48/213 reads (23%) | called by mutect2, varscan2
- GLB1L2 | c.1420del p.L474* | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- GPR37 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIA1 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GRIP2 | c.3183del p.G1062Vfs*53 (on ENST00000619221; = p.G965Vfs*53 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, varscan2
- GTF3C1 | c.4580del p.L1527Wfs*46 | Frame Shift Del (DEL) | VAF 40/188 reads (21%) | called by mutect2, pindel
- HSP90AB1 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- HTR1B | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- IFRD1 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGFN1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INPP4A | c.2651G>A p.C884Y (on ENST00000074304 / NM_001134224.1; = p.C845Y on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRF5 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- IRS1 | c.2195A>G p.Y732C | Missense Mutation (SNP) | VAF 13/395 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 52/188 reads (28%) | called by mutect2, varscan2
- JAK1 | c.425dup p.I143Dfs*9 | Frame Shift Ins (INS) | VAF 41/192 reads (21%) | called by mutect2, varscan2
- JUNB | c.344del p.G115Vfs*35 | Frame Shift Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- KCNK15 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- KDM5B | c.3355del p.S1119Afs*4 | Frame Shift Del (DEL) | VAF 31/182 reads (17%) | called by mutect2, pindel, varscan2
- KL | c.2384del p.K795Sfs*2 | Frame Shift Del (DEL) | VAF 95/418 reads (23%) | called by pindel, varscan2
- KLF5 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KMT2D | c.12034C>A p.P4012T | Missense Mutation (SNP) | VAF 108/462 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2E | c.5006_5009del p.H1669Lfs*42 | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | called by pindel, varscan2
- KMT5C | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- L3MBTL2 | c.1398del p.S468Pfs*73 | Frame Shift Del (DEL) | VAF 45/175 reads (26%) | called by mutect2, pindel, varscan2
- LENG1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LIMD1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LIPE | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC19 | c.805del p.S269Vfs*13 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- LRRC4C | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LSR | c.1269del p.S424Vfs*8 (on ENST00000361790; = p.S405Vfs*8 on NM_015925.6) | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- MUC5AC | c.16802G>A p.S5601N | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- NEB | c.16457G>A p.R5486K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NEFL | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 149/628 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NME9 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NOMO1 | c.1913dup p.R639Sfs*7 | Frame Shift Ins (INS) | VAF 29/228 reads (13%) | called by mutect2, pindel, varscan2
- NPAT | c.3787A>G p.S1263G | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHS1 | c.2102G>A p.S701N | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTN3 | c.602del p.P201Qfs*15 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- NTN4 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR5B12 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PDLIM4 | c.504del p.S169Afs*50 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- PDX1 | c.732del p.G245Efs*61 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | called by mutect2, pindel, varscan2
- PKD1L3 | c.1462G>T p.G488* | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.1117del p.Q373Rfs*22 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- PLIN1 | c.326del p.P109Lfs*8 | Frame Shift Del (DEL) | VAF 44/195 reads (23%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- POMK | c.282_282+1del | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | called by pindel, varscan2
- POU4F1 | c.1187del p.K396Rfs*18 | Frame Shift Del (DEL) | VAF 78/340 reads (23%) | called by mutect2, pindel, varscan2
- PPARGC1B | c.408del p.S137Afs*69 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.792+4G>A | Splice Region (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2
- PRNP | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- PTMA | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2
- RAB8B | c.327_342del p.H109Qfs*4 | Frame Shift Del (DEL) | VAF 21/119 reads (18%) | called by mutect2, pindel
- RAD9B | c.1023_1024del p.C341Wfs*14 | Frame Shift Del (DEL) | VAF 77/334 reads (23%) | called by pindel, varscan2
- RAI1 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- RAPGEF6 | c.3888G>T p.Q1296H | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASEF | c.2141del p.K714Rfs*10 | Frame Shift Del (DEL) | VAF 29/129 reads (22%) | called by pindel, varscan2
- RNPC3 | c.873_874del p.P292Ffs*19 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | called by pindel, varscan2
- RTN4RL2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RUFY2 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- RUFY2 | c.1560dup p.E521Rfs*4 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | called by mutect2, pindel
- SALL2 | c.1125C>A p.C375* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- SARDH | c.1619G>T p.R540M | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- SASH1 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, varscan2
- SBNO1 | c.2639A>C p.E880A (on ENST00000420886; = p.E879A on NM_018183.5) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SBNO1 | c.2638G>A p.E880K (on ENST00000420886; = p.E879K on NM_018183.5) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SCARF1 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SELP | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SEMA3F | c.1859G>A p.S620N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SERPINH1 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 122/484 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SH2D3A | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SLC25A22 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 95/436 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); called by muse, varscan2
- SLC25A22 | c.588-2A>C p.X196_splice | Splice Site (SNP) | VAF 39/286 reads (14%) | called by muse, varscan2
- SLF1 | c.1056del p.F352Lfs*22 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- SNX18 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SRCAP | c.8952T>A p.C2984* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- SYCE1L | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SZT2 | c.7896C>A p.F2632L (on ENST00000634258 / NM_001365999.1; = p.F2575L on NM_015284.4) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TLX1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMCC1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53BP2 | c.2927G>A p.G976D (on ENST00000343537 / NM_001031685.3; = p.G847D on NM_005426.2) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP73 | c.111del p.N38Ifs*20 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.98del p.G33Vfs*23 | Frame Shift Del (DEL) | VAF 52/247 reads (21%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.1136T>A p.I379N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UCN | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WFIKKN2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- WIF1 | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WNT2B | c.428A>G p.Y143C (on ENST00000369684 / NM_024494.3; = p.Y124C on NM_004185.4) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- XIRP2 | c.92G>A p.R31Q (on ENST00000628543; = p.R206Q on NM_152381.6) | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- YLPM1 | c.2532del p.F844Lfs*23 | Frame Shift Del (DEL) | VAF 39/143 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB2 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZBTB39 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF160 | c.1757T>G p.V586G | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF407 | c.5837del p.G1946Afs*18 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- ZNF485 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF865 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ZSCAN12 | c.1276A>G p.N426D | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACACB | c.4089C>T p.C1363= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- ADAM28 | c.354C>T p.D118= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs144018592; called by muse, mutect2, varscan2
- AKT2 | c.597C>T p.T199= | Silent (SNP) | VAF 30/474 reads (6%) | catalogued as rs538944575; called by muse, mutect2
- ANKRD11 | c.7920C>T p.C2640= | Silent (SNP) | VAF 16/375 reads (4%) | called by muse, mutect2
- ARHGAP6 | c.633G>A p.L211= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs780933990, COSV57295815; called by muse, mutect2, varscan2
- BCAN | c.1401G>A p.E467= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs377376223; called by muse, mutect2
- BCL11B | c.1113G>A p.A371= (on ENST00000357195 / NM_001282237.2; = p.A300= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- BMS1 | c.2799G>A p.K933= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs970364738; called by muse, mutect2, varscan2
- CACNA1H | c.2742C>T p.N914= | Silent (SNP) | VAF 58/239 reads (24%) | catalogued as rs375091126; ClinVar: likely benign; called by muse, mutect2, varscan2
- CILP2 | c.2151C>T p.G717= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- COL4A1 | c.2031G>A p.L677= | Silent (SNP) | VAF 90/372 reads (24%) | called by muse, mutect2, varscan2
- CPXM1 | c.864G>A p.A288= | Silent (SNP) | VAF 41/216 reads (19%) | catalogued as rs200841971; called by muse, mutect2, varscan2
- CR1 | c.2460G>A p.V820= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- DDX11 | c.489A>G p.E163= | Silent (SNP) | VAF 87/382 reads (23%) | catalogued as COSV52503334; called by muse, varscan2
- DLX2 | c.228C>T p.G76= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as rs747778233, COSV99308622; called by muse, varscan2
- E4F1 | c.816C>A p.P272= | Silent (SNP) | VAF 49/253 reads (19%) | called by muse, mutect2, varscan2
- ENO4 | c.705C>T p.G235= (on ENST00000622726; = p.G234= on NM_001242699.2) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV58006070; called by muse, mutect2, varscan2
- EPB41L4B | c.2322C>T p.P774= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs1468379724; called by muse, mutect2, varscan2
- FIBIN | c.160C>T p.L54= | Silent (SNP) | VAF 46/250 reads (18%) | called by muse, mutect2, varscan2
- FLNC | c.4221G>A p.V1407= | Silent (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- FURIN | c.927C>T p.T309= | Silent (SNP) | VAF 56/256 reads (22%) | called by muse, mutect2, varscan2
- GATA6 | c.249C>T p.Y83= | Silent (SNP) | VAF 69/234 reads (29%) | called by muse, mutect2, varscan2
- GJD2 | c.207C>T p.R69= | Silent (SNP) | VAF 57/259 reads (22%) | catalogued as rs199516045; called by muse, mutect2, varscan2
- GLB1L2 | c.219G>A p.V73= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- GNB1 | c.444C>T p.C148= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- GNS | c.414A>G p.S138= | Silent (SNP) | VAF 42/285 reads (15%) | called by muse, mutect2, varscan2
- GPR101 | c.180G>A p.P60= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1446681282; called by muse, mutect2, varscan2
- GRIA1 | c.1197C>T p.G399= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs772173588, COSV53614289; called by muse, mutect2, varscan2
- GSN | c.1803C>T p.A601= | Silent (SNP) | VAF 68/321 reads (21%) | catalogued as rs756482045, COSV100376266; called by muse, mutect2, varscan2
- GSX1 | c.561C>T p.S187= | Silent (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- HCRTR2 | c.372G>A p.Q124= | Silent (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- HTR1E | c.996C>T p.L332= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1056270836; called by muse, mutect2, varscan2
- IKZF1 | c.669C>T p.C223= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV58789862; called by muse, mutect2, varscan2
- IL18R1 | c.1155C>T p.C385= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV104374714; called by muse, mutect2, varscan2
- IRS2 | c.2241C>T p.C747= | Silent (SNP) | VAF 42/444 reads (9%) | catalogued as rs763344749; called by muse, mutect2
- KCNN2 | c.288T>C p.G96= (on ENST00000264773; = p.G308= on NM_021614.4) | Silent (SNP) | VAF 50/276 reads (18%) | catalogued as COSV53289396; called by muse, mutect2, varscan2
- KLF7 | c.672C>T p.N224= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs201005804, COSV58743383; called by muse, mutect2, varscan2
- KMT2A | c.7570C>T p.L2524= | Silent (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- KRT36 | c.288T>C p.T96= | Silent (SNP) | VAF 33/369 reads (9%) | called by muse, mutect2
- KRTAP10-11 | c.288G>A p.Q96= | Silent (SNP) | VAF 107/473 reads (23%) | catalogued as COSV100552551; called by muse, mutect2, varscan2
- LDOC1 | c.354C>T p.Y118= | Silent (SNP) | VAF 85/341 reads (25%) | catalogued as COSV65159725; called by muse, mutect2, varscan2
- LIMCH1 | c.1416A>G p.T472= | Silent (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- LMF2 | c.579G>A p.A193= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs951110066; called by muse, mutect2, varscan2
- LPAR5 | c.408C>T p.R136= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- LRPPRC | c.171G>A p.R57= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs1378376157; called by muse, mutect2, varscan2
- LRRC14 | c.822C>T p.R274= | Silent (SNP) | VAF 45/199 reads (23%) | catalogued as rs768390919; called by muse, mutect2, varscan2
- LVRN | c.270G>A p.P90= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs1451360264, COSV63496592, COSV63497651; called by muse, mutect2, varscan2
- MAML3 | c.2955C>T p.G985= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as rs1315227298, COSV72209055; called by muse, mutect2, varscan2
- MEIS1 | c.687A>G p.P229= | Silent (SNP) | VAF 64/316 reads (20%) | called by muse, mutect2, varscan2
- MPV17L | c.123C>T p.R41= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs891777693; called by muse, varscan2
- MTMR6 | c.1726C>T p.L576= | Silent (SNP) | VAF 48/254 reads (19%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1350G>A p.V450= | Silent (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- NKX1-1 | c.195C>T p.P65= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- NKX3-2 | c.21C>T p.N7= | Silent (SNP) | VAF 66/264 reads (25%) | called by muse, mutect2, varscan2
- OR8D4 | c.339C>T p.Y113= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as rs1212851924; called by muse, mutect2, varscan2
- PCDHA13 | c.1098C>T p.S366= | Silent (SNP) | VAF 52/270 reads (19%) | catalogued as rs34923516, COSV56539635; called by muse, mutect2, varscan2
- PLEKHA2 | c.717G>A p.L239= | Silent (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.729G>A p.P243= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs1432460025, COSV55341980; called by muse, mutect2, varscan2
- PPL | c.1176G>A p.K392= | Silent (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- PPP1R37 | c.747G>A p.L249= | Silent (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- PRKDC | c.11376C>T p.S3792= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs1210023685; called by muse, mutect2, varscan2
- PUF60 | c.222C>A p.A74= | Silent (SNP) | VAF 52/210 reads (25%) | catalogued as rs1447921204; called by muse, mutect2, varscan2
- PVALB | c.285C>T p.D95= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs779969972, COSV53411865; called by muse, mutect2, varscan2
- RALGAPA2 | c.2304C>T p.S768= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as rs551297065; called by muse, mutect2
- SELENOV | c.459G>A p.P153= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV100112915; called by muse, mutect2, varscan2
- SEMA3F | c.945C>T p.S315= | Silent (SNP) | VAF 42/191 reads (22%) | called by muse, mutect2, varscan2
- SIN3B | c.3477G>A p.P1159= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs367576931; called by muse, mutect2, varscan2
- SLC2A5 | c.796C>T p.L266= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- SLC4A3 | c.2574T>C p.P858= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- SORCS1 | c.339G>A p.A113= | Silent (SNP) | VAF 67/255 reads (26%) | catalogued as rs749403360, COSV53864103; called by muse, mutect2, varscan2
- SOX10 | c.1293G>A p.S431= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as rs144116155; called by muse, mutect2, varscan2
- SRRM1 | c.1218T>C p.T406= | Silent (SNP) | VAF 64/322 reads (20%) | called by muse, mutect2, varscan2
- STK11 | c.765C>T p.F255= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs769912677, COSV100481013, COSV58829443; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUSD4 | c.1119C>T p.P373= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as rs536188464; called by muse, mutect2, varscan2
- SYNJ1 | c.1407C>T p.S469= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs919941488, COSV59149569; called by muse, mutect2, varscan2
- TAF7 | c.318T>C p.P106= | Silent (SNP) | VAF 40/190 reads (21%) | called by muse, mutect2, varscan2
- THBD | c.1662C>T p.C554= | Silent (SNP) | VAF 55/210 reads (26%) | catalogued as rs903959463, COSV65702039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMC7 | c.990G>A p.L330= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TMEM132E | c.312G>A p.A104= | Silent (SNP) | VAF 60/236 reads (25%) | catalogued as rs1319452505; called by muse, varscan2
- TMEM145 | c.204C>T p.C68= | Silent (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.25626C>A p.L8542= (on ENST00000591111; = p.L7615= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- TUBB1 | c.480G>A p.P160= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as rs375178427; called by muse, mutect2, varscan2
- UBE2O | c.2388C>T p.A796= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs1016866913, COSV60064752; called by muse, mutect2, varscan2
- USP48 | c.2127T>C p.H709= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- WDR24 | c.1986C>T p.S662= (on ENST00000248142; = p.S532= on NM_032259.4) | Silent (SNP) | VAF 57/240 reads (24%) | catalogued as rs745457699, COSV50198088; called by muse, mutect2, varscan2
- WSCD1 | c.1456C>T p.L486= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as COSV58494816; called by muse, mutect2, varscan2
- ZDHHC9 | c.84C>T p.R28= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as rs959475974, COSV64096475; called by muse, mutect2, varscan2
- ZFPM2 | c.2091C>T p.S697= | Silent (SNP) | VAF 110/455 reads (24%) | catalogued as rs1255343246; called by muse, mutect2, varscan2
- ZNF143 | c.1713A>G p.A571= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as rs781049072; called by muse, mutect2, varscan2
- ABCC8 | c.4308-46C>T | Intron (SNP) | VAF 38/130 reads (29%) | catalogued as rs961820480; called by muse, mutect2, varscan2
- AC025575.2 | n.272G>A | RNA (SNP) | VAF 24/89 reads (27%) | catalogued as rs1478348086; called by muse, varscan2
- AC244394.2 | n.1316C>A | RNA (SNP) | VAF 63/267 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.825-66_825-64del | Intron (DEL) | VAF 30/152 reads (20%) | called by pindel, varscan2
- AFDN | chr6:167825836 G>T | 5'Flank (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2
- AL109984.1 | n.186+1061T>C | Intron (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- ANKRD11 | c.87+3523C>A | Intron (SNP) | VAF 81/301 reads (27%) | called by muse, mutect2, varscan2
- ATXN2L | c.*393C>T | 3'UTR (SNP) | VAF 43/132 reads (33%) | catalogued as rs991482463, COSV57367043; called by muse, mutect2, varscan2
- C2CD6 | c.1581+1741del | Intron (DEL) | VAF 18/66 reads (27%) | catalogued as rs376868287; called by mutect2, varscan2
- CABIN1 | c.4117+57dup | Intron (INS) | VAF 40/169 reads (24%) | catalogued as rs766082760; called by mutect2, varscan2
- CD8A | c.*130C>T | 3'UTR (SNP) | VAF 88/392 reads (22%) | called by muse, mutect2, varscan2
- CEP78 | c.2059+17dup | Intron (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel
- CHD1 | c.4428-137A>G | Intron (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- COL1A2 | c.2349+28C>T | Intron (SNP) | VAF 64/333 reads (19%) | catalogued as rs774428414; called by muse, mutect2, varscan2
- COL4A2 | c.648+222C>T | Intron (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- CROCC | c.-1del | 5'UTR (DEL) | VAF 25/155 reads (16%) | catalogued as rs201470726; called by mutect2, pindel, varscan2
- DOCK8 | c.53+14del | Intron (DEL) | VAF 39/170 reads (23%) | catalogued as rs749863710; called by mutect2, pindel, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 20/88 reads (23%) | catalogued as rs1446348498; called by mutect2, pindel
- EYS | c.862+33C>T | Intron (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2
- FAM126A | c.*16del | 3'UTR (DEL) | VAF 30/122 reads (25%) | called by mutect2, varscan2
- FOXP2 | c.*1386G>A | 3'UTR (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- GANC | c.*2213del | 3'UTR (DEL) | VAF 8/94 reads (9%) | catalogued as rs1248831806; called by mutect2, pindel
- GCSH | c.149-14G>A | Intron (SNP) | VAF 56/302 reads (19%) | called by muse, mutect2, varscan2
- HSPA12A | c.41-51dup | Intron (INS) | VAF 30/155 reads (19%) | catalogued as rs1212142040; called by mutect2, pindel, varscan2
- IDI1 | c.537+62T>C | Intron (SNP) | VAF 65/188 reads (35%) | catalogued as rs1040172745; called by muse, mutect2, varscan2
- KDR | c.1987+27G>A | Intron (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- LAT | c.-7C>A | 5'UTR (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- LILRB1 | chr19:54630611 G>T | 5'Flank (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- MAP7D1 | c.2026-22C>T | Intron (SNP) | VAF 46/277 reads (17%) | catalogued as COSV60215774; called by muse, mutect2, varscan2
- MATR3 | c.*169del | 3'UTR (DEL) | VAF 8/58 reads (14%) | catalogued as rs375682201; called by mutect2, varscan2
- MGAT4FP | n.980dup | RNA (INS) | VAF 31/145 reads (21%) | catalogued as rs1347535531; called by mutect2, varscan2
- MIR517B | n.46G>A | RNA (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- MRPS28 | c.396-39279T>A | Intron (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- MTFR1L | chr1:25820255 A>G | 5'Flank (SNP) | VAF 108/466 reads (23%) | catalogued as rs1185993493; called by muse, mutect2, varscan2
- NARF | c.-34T>C | 5'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- NEFH | c.*47_*49dup | 3'UTR (INS) | VAF 90/401 reads (22%) | called by mutect2, pindel, varscan2
- NF2 | c.*16C>T | 3'UTR (SNP) | VAF 68/361 reads (19%) | catalogued as rs1163044481; called by muse, mutect2, varscan2
- NOD2 | c.-25T>C | 5'UTR (SNP) | VAF 65/286 reads (23%) | called by muse, mutect2, varscan2
- NPM2 | c.567-11C>T | Intron (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- NRBP2 | c.*186del | 3'UTR (DEL) | VAF 14/42 reads (33%) | catalogued as rs1239273376; called by mutect2, pindel, varscan2
- OR10AB1P | n.742C>T | RNA (SNP) | VAF 58/178 reads (33%) | catalogued as rs979402886; called by muse, varscan2
- PAK4 | c.-2C>T | 5'UTR (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2
- PANK2 | c.628+194del | Intron (DEL) | VAF 27/131 reads (21%) | called by mutect2, varscan2
- PGLYRP1 | chr19:46018962 G>T | 3'Flank (SNP) | VAF 31/146 reads (21%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.414-42G>A | Intron (SNP) | VAF 56/276 reads (20%) | catalogued as rs751682577; called by muse, mutect2, varscan2
- PRPF3 | c.1759+42C>T | Intron (SNP) | VAF 11/259 reads (4%) | called by muse, mutect2
- PSD4 | c.2770-73del | Intron (DEL) | VAF 22/121 reads (18%) | catalogued as rs1558658758; called by mutect2, pindel, varscan2
- PTBP3 | chr9:112220259 C>A | 3'Flank (SNP) | VAF 31/142 reads (22%) | catalogued as rs1456171784; called by muse, mutect2, varscan2
- RAPGEF3 | c.-10-17C>T | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- RARS2 | c.*24del | 3'UTR (DEL) | VAF 46/201 reads (23%) | called by mutect2, pindel, varscan2
- RPGR | c.2520+425del | Intron (DEL) | VAF 20/110 reads (18%) | catalogued as CD083335; called by mutect2, pindel, varscan2
- RPL4 | c.422-149C>A | Intron (SNP) | VAF 25/124 reads (20%) | catalogued as rs376961183; called by muse, mutect2, varscan2
- SLC12A8 | c.737-95A>G | Intron (SNP) | VAF 44/218 reads (20%) | catalogued as rs1360724937; called by muse, mutect2, varscan2
- SMG1P1 | n.494G>T | RNA (SNP) | VAF 5/17 reads (29%) | catalogued as rs1400901997; called by mutect2, varscan2
- SNORD115-38 | n.44G>A | RNA (SNP) | VAF 36/210 reads (17%) | catalogued as rs751475781; called by muse, mutect2, varscan2
- SSPOP | n.9793del | RNA (DEL) | VAF 58/223 reads (26%) | catalogued as rs770564198, COSV100947664; called by mutect2, pindel, varscan2
- STX1A | c.679-11del | Intron (DEL) | VAF 25/133 reads (19%) | catalogued as COSV56096037, COSV99737195; called by mutect2, pindel, varscan2
- SYPL1 | c.-16_-12delinsCGC | 5'UTR (DEL) | VAF 38/189 reads (20%) | called by pindel, varscan2*
- TCIRG1 | c.1021-31C>A | Intron (SNP) | VAF 77/309 reads (25%) | called by muse, mutect2, varscan2
- TCP1 | c.377+169del | Intron (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- TLR3 | c.634-12del | Intron (DEL) | VAF 26/134 reads (19%) | catalogued as rs746858510; called by mutect2, varscan2
- TUBB8P7 | n.1544G>A | RNA (SNP) | VAF 20/340 reads (6%) | catalogued as rs559155623; called by muse, mutect2
- TUBGCP4 | c.385-48del | Intron (DEL) | VAF 25/100 reads (25%) | catalogued as rs913358416; called by mutect2, varscan2
- VSIG10L2 | chr11:125943648 G>A | 5'Flank (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2
- WASF4P | n.386C>A | RNA (SNP) | VAF 75/306 reads (25%) | called by muse, mutect2, varscan2
- WASHC2A | c.*520del | 3'UTR (DEL) | VAF 32/274 reads (12%) | called by mutect2, varscan2
- XIAP | c.*2529del | 3'UTR (DEL) | VAF 68/281 reads (24%) | called by mutect2, pindel, varscan2
- XPC | c.*427C>T | 3'UTR (SNP) | VAF 8/80 reads (10%) | catalogued as rs756382906; called by muse, mutect2
- ZNF638 | c.2378-2640G>A | Intron (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- ZNRD1ASP | chr6:30009068 C>T | 3'Flank (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
